Gene-level copy-number profile of tumor specimen TCGA-G4-6626-01A from TCGA case TCGA-G4-6626, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-G4-6626-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.79bf4d14-1f39-4671-b646-9736bd941b58.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G4-6626-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f6c8b333-3b2e-4586-9ff9-cfd88b6fc7b2

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 550; copy number 2: 15,435; copy number 3: 21,883; copy number 4: 8,989; copy number 5: 10,732; copy number 6: 648; copy number 7: 626; copy number 8: 898; copy number 12: 2; copy number 14: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-G4-6626-01A-11D-1770-01): tumor purity 0.6, ploidy 3.41, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:77,672,215–77,918,011, 3 genes: AC084149.1, RPL38P2, LINC01851.
- chr16:6,037,210–7,004,112, 9 genes: AC009135.2, AC009135.1, AC006112.1, AC007223.1, AC007012.2, AC007012.1, RNU7-99P, RNU6-457P, RNU6-328P.
- chr20:14,884,250–15,022,958, 4 genes: MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,561 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:31,193,686–31,329,146, 2 genes, copy number 8 (within-gene range 6–8): CDH6, DUX4L51.
- chr8:35,080,592–40,520,158, 110 genes, copy number 7–14 (broad region; genes not listed).
- chr20:87,250–13,996,443, 281 genes, copy number 7 (broad region; genes not listed).
- chr20:14,003,508–14,758,056, 9 genes, copy number 7: RPS3P1, AIMP1P1, RN7SL864P, FLRT3, RNU6-228P, AL121582.1, RNF11P2, MACROD2-IT1, RPS10P2.
- chr20:16,177,933–64,313,132, 1,159 genes, copy number 7–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 550. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
